Somatic mutation profile of tumor specimen C3L-05781-01 (aliquot CPT0306060006) from CPTAC case C3L-05781, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 61.8 years (22,556 days).
Specimen C3L-05781-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0400ee0b-f8a1-4ada-bd1e-8878afa89bdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05781-31 (Blood Derived Normal), aliquot CPT0306160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523069e3-2c7d-4cf2-b5fd-a6d9af3ce870

The open-access MAF lists 136 somatic variants for this specimen: 85 protein-altering or splice-affecting, 44 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 44, Intron 5, Nonsense Mutation 4, Splice Region 2, Splice Site 1, RNA 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 215/357 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 148/326 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: pathogenic / risk factor / likely pathogenic; called by muse, varscan2
- COL7A1 | c.4894C>T p.R1632* | Nonsense Mutation (SNP) | VAF 190/439 reads (43%) | catalogued as rs751535193, CM992840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEB | c.8889+1G>A p.X2963_splice | Splice Site (SNP) | VAF 92/230 reads (40%) | catalogued as rs1553963960; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 28/218 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AC008397.2 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 186/459 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53208762; called by muse, mutect2, varscan2
- ANKLE1 | c.748C>T p.P250S (on ENST00000394458; = p.P196S on NM_152363.6) | Missense Mutation (SNP) | VAF 195/490 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV63920194; called by muse, mutect2, varscan2
- ASPHD2 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 231/512 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV53220800; called by muse, mutect2, varscan2
- ATG2A | c.4736G>A p.R1579H | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776977388, COSV65966539; called by muse, varscan2
- ATP7B | c.4187C>T p.T1396M | Missense Mutation (SNP) | VAF 196/447 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs528603867, COSV54434713, COSV54434723; called by muse, mutect2, varscan2
- BSN | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 229/526 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs767558019, COSV56515063; called by muse, mutect2, varscan2
- C8orf34 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs868113803, COSV61381717; called by muse, mutect2, varscan2
- CAPN13 | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369279197; called by muse, mutect2, varscan2
- CSMD1 | c.1639G>A p.G547R (on ENST00000520002; = p.G546R on NM_033225.6) | Missense Mutation (SNP) | VAF 202/462 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs373233217; called by muse, mutect2, varscan2
- DNAH5 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 165/439 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV99446296; called by muse, mutect2, varscan2
- DSG2 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 190/451 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs753406968, COSV55196565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZHIP | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 218/241 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV57957185; called by muse, mutect2, varscan2
- FUT3 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 204/710 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs267605641, COSV54608699; called by muse, varscan2
- GSTT2B | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs1363192467; called by mutect2, varscan2
- H2BE1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 428/703 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1049726369; called by muse, mutect2, varscan2
- HEPACAM2 | c.1116G>A p.W372* (on ENST00000394468 / NM_001039372.4; = p.W360* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 145/266 reads (55%) | catalogued as COSV59062430; called by muse, mutect2, varscan2
- INCENP | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); catalogued as rs1244205548; called by muse, mutect2, varscan2
- KANK4 | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 174/430 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs532994942; called by muse, varscan2
- MGAM2 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 176/332 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867891460, COSV104438575; called by muse, mutect2, varscan2
- MIDEAS | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 219/553 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs374989771; called by muse, mutect2, varscan2
- NRG1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428189069; called by muse, mutect2, varscan2
- OR2C3 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 199/451 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV63574368; called by muse, mutect2, varscan2
- OR4C15 | c.453G>A p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 230/511 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs763726329, COSV58951556; called by muse, mutect2, varscan2
- OTX2 | c.638C>T p.P213L (on ENST00000408990 / NM_172337.3; = p.P221L on NM_021728.4) | Missense Mutation (SNP) | VAF 211/458 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV59766759; called by muse, mutect2, varscan2
- PADI4 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 174/241 reads (72%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV100966664; called by muse, varscan2
- PKHD1L1 | c.6076C>T p.P2026S | Missense Mutation (SNP) | VAF 178/411 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.673); catalogued as COSV65748468; called by muse, mutect2, varscan2
- PLEKHH2 | c.3415G>T p.A1139S | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV99174711; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 269/943 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2, varscan2
- PRB2 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 82/272 reads (30%) | PolyPhen benign (0.077); catalogued as COSV101231487; called by muse, mutect2, varscan2
- PRB2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 151/378 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.261); catalogued as rs1309865839; called by mutect2, varscan2
- PRKD3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 165/389 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV52214767; called by muse, mutect2, varscan2
- PROX2 | c.1676G>A p.G559E (on ENST00000556489 / NM_001243007.1; = p.G332E on NM_001080408.2) | Missense Mutation (SNP) | VAF 180/414 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755884628; called by muse, mutect2, varscan2
- SLC30A10 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745609179, COSV63072002; called by muse, mutect2, varscan2
- SLC4A1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs777378002, COSV99293360; called by muse, varscan2
- SLC4A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 130/356 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs1451658424; called by muse, mutect2, varscan2
- TIGIT | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs201219748; called by muse, mutect2, varscan2
- TTC17 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as rs139809583; called by muse, mutect2, varscan2
- AL117348.2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 192/482 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKMY1 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 191/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPG | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 156/435 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CACNA2D3 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 172/407 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC146 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 142/525 reads (27%) | called by muse, mutect2, varscan2
- CHD1 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIP2A | c.2645C>T p.S882F | Missense Mutation (SNP) | VAF 174/417 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- COL5A2 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- COL6A5 | c.7764A>C p.K2588N (on ENST00000312481; = p.K2584N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CUL2 | c.117C>T p.F39= | Splice Region (SNP) | VAF 112/138 reads (81%) | called by muse, mutect2, varscan2
- DCLK2 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 169/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DEUP1 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DPY19L4 | c.1250C>G p.T417R | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.7864C>G p.P2622A | Missense Mutation (SNP) | VAF 145/353 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- GNAS | c.1136G>C p.C379S | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA3 | c.3439G>T p.A1147S | Missense Mutation (SNP) | VAF 159/373 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- HAUS5 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 199/889 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HDAC9 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 177/316 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IFT80 | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 130/326 reads (40%) | called by muse, mutect2, varscan2
- JCAD | c.1376C>A p.T459N | Missense Mutation (SNP) | VAF 186/246 reads (76%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); called by mutect2, varscan2
- KCNQ2 | c.1691T>G p.V564G (on ENST00000359125 / NM_172107.4; = p.V536G on NM_004518.6) | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KRT222 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHCGR | c.1937G>C p.R646P | Missense Mutation (SNP) | VAF 182/471 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MYH2 | c.4505A>G p.E1502G | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MYO15B | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- PHLDA1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 159/434 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIEZO2 | c.4662T>G p.F1554L | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIK3R5 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 117/289 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PLEC | c.13559C>T p.A4520V (on ENST00000322810 / NM_201380.4; = p.A4410V on NM_000445.5) | Missense Mutation (SNP) | VAF 236/539 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- POTEG | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 123/1126 reads (11%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRB2 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RHCE | c.1227G>A p.K409= | Splice Region (SNP) | VAF 92/134 reads (69%) | called by muse, mutect2, varscan2
- RNF212 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 74/110 reads (67%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2
- RTN2 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCN3A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SEMA3D | c.727T>A p.F243I | Missense Mutation (SNP) | VAF 146/251 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUN2 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 150/374 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIE1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 178/415 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TOM1L1 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UMOD | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF556 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 346/580 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF616 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ZNF813 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ABCC1 | c.4116C>T p.I1372= | Silent (SNP) | VAF 94/240 reads (39%) | called by muse, mutect2, varscan2
- ABCG2 | c.1878G>A p.L626= | Silent (SNP) | VAF 183/443 reads (41%) | called by muse, mutect2, varscan2
- ADGRL2 | c.4191C>T p.S1397= (on ENST00000370717 / NM_001366005.1; = p.S1341= on NM_012302.4) | Silent (SNP) | VAF 170/429 reads (40%) | catalogued as rs147604439; called by muse, mutect2, varscan2
- AXIN2 | c.1599G>A p.A533= | Silent (SNP) | VAF 166/388 reads (43%) | catalogued as rs188003998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALCR | c.504G>A p.G168= | Silent (SNP) | VAF 108/430 reads (25%) | catalogued as COSV64005671; called by muse, mutect2, varscan2
- CCSER1 | c.2574C>A p.T858= | Silent (SNP) | VAF 173/376 reads (46%) | called by muse, mutect2, varscan2
- CD163L1 | c.459G>T p.L153= | Silent (SNP) | VAF 111/154 reads (72%) | called by muse, mutect2, varscan2
- CD9 | c.189G>A p.L63= | Silent (SNP) | VAF 121/341 reads (35%) | called by muse, mutect2, varscan2
- COL5A3 | c.927C>T p.S309= | Silent (SNP) | VAF 135/352 reads (38%) | catalogued as rs1465565108; called by muse, mutect2, varscan2
- CPS1 | c.4017T>G p.G1339= | Silent (SNP) | VAF 130/173 reads (75%) | called by muse, mutect2, varscan2
- CTNND2 | c.2760C>T p.A920= | Silent (SNP) | VAF 171/394 reads (43%) | catalogued as rs1358459713; called by muse, mutect2, varscan2
- FAT2 | c.12054A>G p.G4018= | Silent (SNP) | VAF 111/256 reads (43%) | called by muse, mutect2, varscan2
- GRID2 | c.1410C>T p.F470= | Silent (SNP) | VAF 180/392 reads (46%) | called by muse, mutect2, varscan2
- H2AX | c.357G>A p.K119= | Silent (SNP) | VAF 187/258 reads (72%) | called by muse, mutect2, varscan2
- IPO4 | c.1557C>T p.F519= | Silent (SNP) | VAF 133/328 reads (41%) | called by muse, mutect2, varscan2
- KIAA2026 | c.1392T>C p.D464= | Silent (SNP) | VAF 113/149 reads (76%) | called by muse, mutect2, varscan2
- KL | c.1045C>T p.L349= | Silent (SNP) | VAF 131/334 reads (39%) | called by muse, mutect2, varscan2
- KRTAP9-9 | c.423C>T p.R141= | Silent (SNP) | VAF 295/675 reads (44%) | catalogued as rs1011073076; called by muse, mutect2, varscan2
- LAMP5 | c.444G>A p.S148= | Silent (SNP) | VAF 150/376 reads (40%) | catalogued as COSV55718268; called by muse, mutect2, varscan2
- LCK | c.1111C>T p.L371= | Silent (SNP) | VAF 165/388 reads (43%) | catalogued as rs765140778; called by muse, mutect2, varscan2
- LZTR1 | c.804C>T p.I268= | Silent (SNP) | VAF 164/391 reads (42%) | called by muse, mutect2, varscan2
- MGAM2 | c.2688G>T p.L896= | Silent (SNP) | VAF 307/484 reads (63%) | called by muse, mutect2, varscan2
- MTCL1 | c.4386C>T p.H1462= (on ENST00000306329 / NM_001378206.1; = p.H1143= on NM_015210.4) | Silent (SNP) | VAF 206/492 reads (42%) | catalogued as rs749139382; called by muse, mutect2, varscan2
- MTERF3 | c.741A>G p.A247= | Silent (SNP) | VAF 181/429 reads (42%) | catalogued as COSV54632028; called by muse, mutect2, varscan2
- NLRP8 | c.153G>A p.E51= | Silent (SNP) | VAF 146/388 reads (38%) | called by muse, mutect2, varscan2
- OR10T2 | c.427T>C p.L143= | Silent (SNP) | VAF 163/415 reads (39%) | called by muse, mutect2, varscan2
- OR4C46 | c.558C>T p.A186= | Silent (SNP) | VAF 173/410 reads (42%) | catalogued as rs753222627, COSV60220769; called by muse, mutect2, varscan2
- PGR | c.1830C>T p.I610= | Silent (SNP) | VAF 140/357 reads (39%) | catalogued as rs11571179; called by muse, mutect2, varscan2
- PLCH1 | c.3063C>T p.F1021= (on ENST00000340059 / NM_001130960.2; = p.F1013= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 157/379 reads (41%) | called by muse, mutect2, varscan2
- RELN | c.699G>A p.A233= | Silent (SNP) | VAF 282/499 reads (57%) | catalogued as rs780491620, COSV58988520, COSV58993933; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFPL4A | c.438C>T p.F146= | Silent (SNP) | VAF 99/435 reads (23%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.438C>T p.F146= | Silent (SNP) | VAF 82/627 reads (13%) | called by muse, mutect2
- RGSL1 | c.75C>T p.F25= | Silent (SNP) | VAF 108/295 reads (37%) | called by muse, mutect2, varscan2
- RIN1 | c.822C>T p.V274= | Silent (SNP) | VAF 280/717 reads (39%) | called by muse, mutect2, varscan2
- SCN7A | c.489C>T p.L163= | Silent (SNP) | VAF 91/240 reads (38%) | catalogued as COSV101313250; called by muse, mutect2, varscan2
- SDK1 | c.4821G>A p.L1607= | Silent (SNP) | VAF 269/453 reads (59%) | catalogued as rs866475536, COSV67354691; called by muse, mutect2, varscan2
- SORCS3 | c.2256C>T p.F752= | Silent (SNP) | VAF 105/130 reads (81%) | catalogued as rs149011139; called by muse, mutect2, varscan2
- SPIB | c.366G>A p.P122= | Silent (SNP) | VAF 54/388 reads (14%) | catalogued as rs778109814, COSV54529860; called by muse, varscan2
- STS | c.561C>T p.I187= | Silent (SNP) | VAF 248/291 reads (85%) | catalogued as rs755543529, COSV99481329; called by muse, mutect2, varscan2
- SVOPL | c.363C>T p.F121= | Silent (SNP) | VAF 144/438 reads (33%) | catalogued as rs866419636; called by muse, mutect2, varscan2
- SYNE1 | c.25596C>T p.D8532= (on ENST00000367255 / NM_182961.4; = p.D8484= on NM_033071.3) | Silent (SNP) | VAF 221/572 reads (39%) | catalogued as rs879497063; called by muse, mutect2, varscan2
- USPL1 | c.1713T>C p.H571= | Silent (SNP) | VAF 154/362 reads (43%) | called by muse, mutect2, varscan2
- ZBTB16 | c.333C>T p.I111= | Silent (SNP) | VAF 159/199 reads (80%) | catalogued as rs200027612, COSV100252118; called by muse, mutect2, varscan2
- ZNF662 | c.978C>T p.H326= | Silent (SNP) | VAF 210/496 reads (42%) | called by muse, mutect2, varscan2
- C19orf25 | c.131-945G>T | Intron (SNP) | VAF 157/520 reads (30%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+942C>G | Intron (SNP) | VAF 91/802 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28796G>A | Intron (SNP) | VAF 172/369 reads (47%) | called by muse, mutect2, varscan2
- MGAM | c.4618+3205C>T | Intron (SNP) | VAF 236/267 reads (88%) | called by muse, mutect2, varscan2
- NPAP1L | n.908G>T | RNA (SNP) | VAF 93/239 reads (39%) | called by muse, mutect2, varscan2
- RDH8 | c.-1G>A | 5'UTR (SNP) | VAF 95/242 reads (39%) | catalogued as rs1165317062; called by muse, mutect2, varscan2
- SIRPB1 | c.76+15094C>T | Intron (SNP) | VAF 154/215 reads (72%) | called by muse, mutect2, varscan2
